Somatic mutation profile of tumor specimen ALCH-AE7V-TTP1-A (aliquot ALCH-AE7V-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AE7V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.1 years (22,691 days).
Specimen ALCH-AE7V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac1947f3-8704-468b-9bd8-54c7fba4399c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE7V-NB1-A (Blood Derived Normal), aliquot ALCH-AE7V-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7b4d373-e9e2-4381-858b-2faa19676924

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, 3'Flank 1, 3'UTR 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFC | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1267429432; called by muse, mutect2
- DDX21 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV100826531; called by muse, mutect2, varscan2
- PCDHGA1 | c.1888C>G p.R630G | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs1316392656, COSV65295964; called by muse, mutect2
- RPAP3 | c.1002A>C p.E334D | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as COSV99139450; called by muse, mutect2
- SPAM1 | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV56143933; called by muse, mutect2
- SRP68 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 22/389 reads (6%) | catalogued as COSV57163662; called by muse, mutect2
- ANKAR | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 43/748 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- ARAP3 | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2
- CARD11 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2
- CYP3A4 | c.1400G>T p.G467V (on ENST00000336411; = p.G436V on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/426 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- ENPEP | c.356T>A p.V119E | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); called by muse, mutect2
- MPP4 | c.948G>T p.W316C | Missense Mutation (SNP) | VAF 19/424 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2
- PCDH17 | c.2121G>T p.P707= | Silent (SNP) | VAF 9/233 reads (4%) | catalogued as COSV64972451; called by muse, mutect2
- CSRP3 | c.*50G>C | 3'UTR (SNP) | VAF 13/344 reads (4%) | called by muse, mutect2
- TPM3 | chr1:154158993 T>C | 3'Flank (SNP) | VAF 36/790 reads (5%) | called by muse, mutect2
